Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96O, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96O-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

ICD-O-3

Thymoma, type B1,
malignant 8583/3

Site Anterior mediastinum
C38.1

W 4/14/14

Pathology Report-Summary:

Material:

Tumor: 7.0 x 4.5 x 3.0 cm

multi focal invasion through capsule into mediastinal fat tissue and lung parenchyma

Diagnosis:

Type B1-Thymoma

pT3, pN0 (0/6)

Masaoka: III

Immunohistochemistry

epithelial cells positive for: CK 5/6, EGFR, weakly positive for KL1

epithelial cells negative for: CD5, CD117

CD1a-, CD99-positive immature T-lymphocytes, and CD5-positive mature T-lymphocytes

sparsely CD20-positive B-lymphocytes

Source: NCI Genomic Data Commons file 371a10f8-4a3f-4627-a741-3500ad614586 (TCGA-ZB-A96O.18DAF7C5-4073-480D-BF00-DD68E3CE421A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).